Gene-level copy-number profile of tumor specimen C3N-00579-02 from CPTAC case C3N-00579, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 67.8 years (24,755 days).
Specimen C3N-00579-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 08eee89e-2ca5-47ca-9e1d-b7e69cc55c8a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00579-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/cdf7d753-dfcc-42e9-a60f-72b667c61016

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 537; copy number 2: 4,865; copy number 3: 2,251; copy number 4: 27,278; copy number 5: 2,531; copy number 6: 18,932; copy number 7: 1,540; copy number 8: 2; copy number 9: 964; copy number 11: 11.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,524,185, 5 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr10:87,591,607–87,845,612, 8 genes: AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P.
- chr10:87,945,502–88,049,823, 3 genes (within-gene range 0–4): RPL11P3, AC063965.1, MED6P1.
- chr15:34,489,002–34,588,503, 6 genes: HNRNPLP2, FSCN1P1, DNM1P5, GOLGA8B, MIR1233-2, AC027139.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 975 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:97,241,742–103,073,051, 138 genes, copy number 9 (broad region; genes not listed).
- chr8:104,590,733–105,804,539, 2 genes, copy number 9 (within-gene range 6–9): ZFPM2, AC012564.1.
- chr8:105,142,860–145,066,685, 568 genes, copy number 9–11 (broad region; genes not listed).
- chr20:53,567,065–64,327,972, 267 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
